Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A94P, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A94P-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

ICD.O-3
Adenocarcinoma, signet
ring cell 8490/3
Site: Gastric body
C16.2
JN 3/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

- "Stomach + epiploon":

Adenocarcinoma characterized as follows:

Location: body and antrum

Histologic pattern(s) observed:

Mucosecreting mucocellular with "signet ring" cells

Histologic grade III - poorly differentiated

Lauren's classification

Measure of the longest axis of the tumor: 4.0cm

Ulceration:

Present

Compromise of:

Serosa

Type of tumor invasion

Spiculated

Inflammatory reaction:

Moderate

Tumor implant in perivisceral adipose tissue:

Not detected

Proximal margin:

Free of neoplastic involvement.

Distal margin:

Free of neoplastic involvement.

Neural infiltration:

Present

Lymphatic vascular invasion:

Present

Sanguineous vascular invasion:

Not detected

Greater omentum:

Free of neoplastic involvement.

Lesser omentum:

Free of neoplastic involvement.

Other lesions: moderate chronic gastritis, with intestinal metaplasia.

[page 2 of 2]
Lymph nodes:

Compromised: 13

Capsular transposition:

Yes

Lymph node conglomerates:

Not detected

Compromised nodes /dissected nodes ratio: 5/13

- Compromised lymph thus discriminated:

4/11 from greater curvature and 2/2 from lesser curvature.

Diagnostic Discrepancy		✓

Source: NCI Genomic Data Commons file b25a15ca-b33e-4dac-a315-5729c20fdd65 (TCGA-VQ-A94P.DFC52337-449F-4788-AC08-4113D1C37C1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).